Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXD-01A (Primary Tumor).

SPEC #:

Status:

Obtained:

Received:

CLINICAL HISTORY:
233.1

100.0.3
Carcinoma, squamous cell, large cell
non-keratinizing N188072/3
Site: Cervix NOS 0539
6/3/13

SPECIMEN/PROCEDURE:
1. CERVIX - BX

IMPRESSION:
CERVICAL BIOPSY:

Squamous cell carcinoma, favor invasive for large cell, nonkeratinizing, grade 2.

Dictated by:
Entered:

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and cervical biopsy. Received is a 1.3 x 1-0.3 cm aggregate of pale pink to red tan irregular tissue fragments. The specimen is entirely submitted in one cassette.

Dictated by:
Entered:

CPT Codes:
CERVICAL BIOPSY/88305

ICD9 Codes:
180.9

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 20c76db0-db44-4c1f-aae2-432650f92b09 (TCGA-ZJ-AAXD.AAEBC293-E409-4B14-9310-6820BA844EE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).